Gene-level copy-number profile of tumor specimen MP2PRT-PAVWBY-TMP1-A from MP2PRT case MP2PRT-PAVWBY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,499 days).
Specimen MP2PRT-PAVWBY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 540f111c-a83b-4a02-9bc7-a887943249d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVWBY-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/364e2b77-1f05-4295-bac6-7c08b4b35977

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 146; copy number 1: 3,869; copy number 2: 54,772; copy number 3: 107.

Homozygous deletions (total copy number 0; autosomes only): 146 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,221,698–89,234,912, 2 genes (within-gene range 0–2): IGKV2-28, IGKV2-29.
- chr9:37,002,697–37,008,040, 1 gene (within-gene range 0–2): AL161781.2.
- chr13:43,883,800–44,405,984, 14 genes (within-gene range 0–2): AL512506.3, AL512506.2, NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2, TUSC8.
- chr13:44,432,144–44,432,678, 1 gene (within-gene range 0–2): AL138960.2.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.
- chr14:105,672,308–106,538,344, 124 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,564,375–106,566,555, 2 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,013. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
